Somatic mutation profile of tumor specimen MMRF_1576_1_BM_CD138pos (aliquot MMRF_1576_1_BM_CD138pos_T1_KBS5U_L05546) from MMRF case MMRF_1576, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.9 years (25,178 days).
Specimen MMRF_1576_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbca7e63-0234-4127-ae60-aa4316ffbeb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1576_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1576_1_PB_Whole_C2_KBS5U_L05565; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79139a9e-8c85-41c7-91ae-f75187bc0431

The open-access MAF lists 92 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 17, Intron 16, Silent 14, 5'UTR 4, 3'Flank 2, Splice Region 2, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2
- TRIOBP | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 68/179 reads (38%) | catalogued as rs118204030, CD060673, CM067725, COSV100730667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BET1 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs773748027; called by muse, mutect2, varscan2
- CTU1 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1179717348, COSV70292782; called by muse, mutect2, varscan2
- DOP1A | c.3994G>C p.E1332Q | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52715924; called by muse, mutect2, varscan2
- DSC3 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as rs569043747; called by muse, mutect2, varscan2
- FLG | c.6528G>T p.R2176S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs777468644, COSV100910621; called by muse, mutect2, varscan2
- FOXM1 | c.693C>G p.N231K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV61207654; called by muse, mutect2, varscan2
- KRT27 | c.925C>G p.R309G | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56972167; called by muse, mutect2
- OFD1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs745573598, COSV60795090; called by muse, mutect2, varscan2
- PDE6A | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs375516599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORL1 | c.5722C>T p.L1908= | Splice Region (SNP) | VAF 103/300 reads (34%) | catalogued as COSV52753712; called by muse, mutect2, varscan2
- TBRG4 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs553260959; called by muse, mutect2, varscan2
- BPIFB3 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CAPN8 | c.1291A>C p.I431L | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CERS1 | c.524A>C p.D175A | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNGA2 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.8599-1G>A p.X2867_splice | Splice Site (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- ERN1 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FUBP1 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2
- FUBP3 | c.1222del p.R408Gfs*14 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- HCFC1 | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HYAL2 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- KCNB1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KIR3DL2 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LYSMD4 | c.864C>G p.F288L (on ENST00000409796 / NM_001284417.2; = p.F289L on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAP1 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PLEKHG2 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXNB2 | c.1565C>A p.T522N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.412); called by muse, mutect2
- SGSH | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SPHKAP | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STXBP5L | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SV2A | c.563T>A p.F188Y | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TMEM104 | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TMSB4X | c.-19C>T | Splice Region (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- VPS33A | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF473 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 62/219 reads (28%) | called by muse, mutect2, varscan2
- ATXN2L | c.837G>C p.V279= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- CHD5 | c.2262T>G p.V754= | Silent (SNP) | VAF 74/171 reads (43%) | called by muse, mutect2, varscan2
- CLDN18 | c.672C>T p.G224= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV51736235; called by muse, mutect2, varscan2
- CRTC3 | c.804G>A p.L268= | Silent (SNP) | VAF 61/233 reads (26%) | called by muse, mutect2, varscan2
- FAM189A1 | c.511C>T p.L171= | Silent (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.132T>C p.D44= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as rs373697673; called by muse, mutect2, varscan2
- IRS1 | c.2931G>A p.R977= | Silent (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- MYO7B | c.1383G>A p.L461= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV67349302; called by muse, mutect2, varscan2
- OLFML2B | c.384C>T p.C128= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs759424305; called by muse, mutect2, varscan2
- PLCB4 | c.2898A>T p.A966= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- PPP1R12C | c.1755G>T p.A585= | Silent (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- TERF2IP | c.177C>T p.P59= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs747932710; called by muse, mutect2, varscan2
- TSPAN19 | c.711C>T p.F237= | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- TTI1 | c.756C>T p.L252= | Silent (SNP) | VAF 102/236 reads (43%) | called by muse, mutect2, varscan2
- ADA2 | c.-114C>A | 5'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- ANKRD42 | c.*17A>G | 3'UTR (SNP) | VAF 122/417 reads (29%) | called by muse, mutect2, varscan2
- ARIH1 | c.*44G>T | 3'UTR (SNP) | VAF 97/486 reads (20%) | catalogued as COSV101134714; called by muse, mutect2, varscan2
- CACNG8 | c.*5170G>A | 3'UTR (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- CGGBP1 | c.-23-663T>C | Intron (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.1071+1641A>C | Intron (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- DENND5B | c.*1676G>A | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DSEL | c.*1114C>T | 3'UTR (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- EMC2 | c.*55G>T | 3'UTR (SNP) | VAF 57/195 reads (29%) | catalogued as rs963172553; called by muse, mutect2, varscan2
- ERGIC2 | c.*2960C>G | 3'UTR (SNP) | VAF 10/16 reads (63%) | catalogued as rs999001712; called by muse, varscan2
- F9 | c.*770A>C | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2
- GABPA | c.*1387G>T | 3'UTR (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- GALNTL6 | c.138+859T>C | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- GAS6 | c.713-74A>G | Intron (SNP) | VAF 13/15 reads (87%) | called by muse, mutect2, varscan2
- GUCD1 | c.*419A>G | 3'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- HLA-DMB | c.-53C>G | 5'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1295+43A>G | Intron (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- LMOD1 | chr1:201946587 C>A | 5'Flank (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- MID1IP1 | c.*887C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+10399C>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- PIEZO2 | c.2492+4424C>G | Intron (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.*186G>A | 3'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- PLOD3 | c.1614+40G>A | Intron (SNP) | VAF 25/73 reads (34%) | catalogued as rs374002462; called by muse, mutect2, varscan2
- PLXNA4 | c.-3G>A | 5'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- PRIMA1 | c.360-4301G>A | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- PRR23B | c.-132G>A | 5'UTR (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+1715del | Intron (DEL) | VAF 84/176 reads (48%) | called by mutect2, pindel, varscan2
- PTPRS | c.3923+61G>A | Intron (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2
- RAB18 | c.68+695C>T | Intron (SNP) | VAF 30/59 reads (51%) | called by mutect2, varscan2
- RAB4B | c.17-55T>C | Intron (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- SF3B1 | c.416-545A>G | Intron (SNP) | VAF 74/81 reads (91%) | called by muse, mutect2, varscan2
- SH2D4B | chr10:80644538 C>T | 3'Flank (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- SHE | c.*1581T>C | 3'UTR (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- SLC25A30 | chr13:45389857 G>T | 3'Flank (SNP) | VAF 59/81 reads (73%) | called by muse, mutect2, varscan2
- SLC2A3 | c.*1875G>A | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- SMR3B | c.*73C>T | 3'UTR (SNP) | VAF 15/365 reads (4%) | called by muse, mutect2
- TCIM | c.*1280C>A | 3'UTR (SNP) | VAF 28/32 reads (88%) | catalogued as rs888026853; called by muse, mutect2, varscan2
- UBQLN1 | c.*1114T>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs1029658040; called by muse, mutect2
- ZNF793 | c.239-19T>G | Intron (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2
- ZSCAN30 | c.553+50A>G | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs527455643; called by muse, mutect2, varscan2
